Surgical pathology report (de-identified scan), TCGA case TCGA-77-8008, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8008-01A (Primary Tumor).

[page 1 of 2]
RIGHT LOWER LOBECTOMY

Clinical Details:

Right lower lobe tumour.

Four specimens submitted:

1: RIGHT LOWER LOBE :

Macroscopy:

The specimen consists of a lobe of lung measuring 110 mm from the hilar/medial margin to the pleural surface x 110 mm superior to inferior x 100 mm anterior to posterior. There is a linear row of staples from anterior to the bronchial margin, 50 mm in length. The staples have been neatly trimmed and the resultant margin inked in black. Upon sectioning through the lung there is a cystic cavity with a diameter of 65 mm. This cavity appears to be surrounded by a fibrous capsule. It is located 2 mm deep to the lateral pleural surface, 12 mm from the stapled resection margin, and 25 mm from the bronchial resection margin. The cystic cavity is filled with much offensive-smelling pink to tan fluid. [Bronchial resection margin, 1A; peribronchial lymph nodes, 1B; longitudinal section through bronchial resection margin to include tumour, 1C; further section of proximal bronchus, this time 20 mm from resection margin to include tumour, 1D; section of inked stapled resection margin to include tumour, 1E; section of lateral pleural surface to include tumour, 1F; section of tumour, 1G; section of macroscopically unremarkable lung, 1H].

Microscopy:

Sections show a moderately differentiated keratinising squamous cell carcinoma with extensive central necrosis and cavitation. There is a heavy lymphoplasmacytic infiltrate in tumour stroma but not within tumour cell islands. Tumour invades into the thickened fibrous pleura but is not present on the pleural surface. No lymphatic or vascular invasion is identified. There is evidence of obstructive pneumonitis in the vicinity of the tumour and more distant lung shows centriacinar emphysema. Peribronchial lymph nodes show anthracosilicosis but no evidence of metastatic carcinoma. The bronchial and vascular resection margins are well clear of malignancy.

2: RIGHT UPPER LOBE SUMP NODE

Macroscopy:

The specimen consists of dark brown to red tissue measuring 12 x 6 x 4 mm. [BIT, 2A].

Microscopy:

Sections show a lymph node with reactive hyperplasia but no evidence of metastatic carcinoma.

3: NO. 11

Macroscopy:

The specimen consists of three pieces of red to brown tissue of varying sizes, with a combined dimension of 15 x 10 x 5 mm. [BIT, 3A].

Microscopy:

Sections show fragments of lymph node in which there is no evidence of malignancy.

4: NO. 7

Macroscopy:

The specimen consists of a piece of soft tissue measuring 60 x 30 x 20 mm. This could be consistent with a large lymph node. [2RS, 4A-4B].

Microscopy:

Sections show a lymph node in which there is reactive hyperplasia but no evidence of metastatic carcinoma.

[page 2 of 2]
[REDACTED]

Conclusion (specimens 1 to 4):

Right lower lobectomy and lymph nodes sampling:

Moderately differentiated keratinising squamous cell carcinoma, 65 mm in diameter.

Pleural invasion present.

No lymphatic or vascular invasion.

No lymph node metastases.

Pathological stage T2 N0.

T-28000 M-80703 P1-03000

Reported by [REDACTED]

Pathology Registrar/Anatomical Pathologist

[REDACTED]

Copies:

[REDACTED]

Source: NCI Genomic Data Commons file c15ca3b0-465f-4c4f-8a46-56994e92242f (TCGA-77-8008.AE32FA6E-D42B-4E6E-93DB-26B1651E8513.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).